Somatic mutation profile of tumor specimen TCGA-GC-A3YS-01A (aliquot TCGA-GC-A3YS-01A-11D-A23M-08) from TCGA case TCGA-GC-A3YS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.6 years (22,515 days).
Specimen TCGA-GC-A3YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b2cc253-731c-406f-afae-e083ec729c11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3YS-10A (Blood Derived Normal), aliquot TCGA-GC-A3YS-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40ad041e-3ade-4a89-a190-2da5e1c53bc1

The open-access MAF lists 263 somatic variants for this specimen: 194 protein-altering or splice-affecting, 64 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 64, Nonsense Mutation 13, Splice Region 4, Splice Site 3, Intron 2, Frame Shift Del 2, 3'Flank 1, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.4366C>T p.R1456* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as rs781043870, COSV55081674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 107/269 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4560G>A p.M1520I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs367930267; called by muse, mutect2, varscan2
- ACACB | c.6806A>G p.D2269G | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.093); catalogued as COSV58128146; called by muse, mutect2, varscan2
- ACHE | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814972; called by muse, mutect2, varscan2
- ADAMTS18 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV51398776; called by muse, mutect2, varscan2
- ADAMTS9 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55775022; called by muse, mutect2, varscan2
- AFF3 | c.2367G>C p.L789F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV57840464; called by muse, mutect2, varscan2
- ANK2 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52146164; called by muse, mutect2, varscan2
- ANLN | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56073942, COSV56080031; called by muse, mutect2, varscan2
- ANXA6 | c.445del p.D149Tfs*23 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as COSV62905509; called by mutect2, pindel, varscan2
- APPL2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs1191290764, COSV51588130; called by muse, mutect2, varscan2
- AQP11 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); catalogued as rs747650973, COSV57992011; called by muse, mutect2, varscan2
- AQP6 | c.564C>T p.I188= | Splice Region (SNP) | VAF 36/58 reads (62%) | catalogued as rs1175623782, COSV59645809; called by muse, mutect2, varscan2
- ARHGAP31 | c.3457G>C p.D1153H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV51789144; called by muse, mutect2, varscan2
- ASCC3 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs765345951, COSV61225840; called by muse, mutect2, varscan2
- ATAD2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV54877333, COSV54878472; called by muse, mutect2
- ATP6V1G2 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | catalogued as rs758603033; called by muse, mutect2, varscan2
- ATXN7L2 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 90/119 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV63992067; called by muse, mutect2, varscan2
- BAZ1A | c.4365G>C p.L1455F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100701085, COSV62408996; called by muse, mutect2, varscan2
- BCL9L | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100600339, COSV58305779; called by muse, mutect2, varscan2
- BFSP1 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV64899348; called by muse, mutect2, varscan2
- BSN | c.9409G>A p.D3137N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV56512988; called by muse, mutect2, varscan2
- C1GALT1C1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV58973727; called by muse, mutect2, varscan2
- C8orf34 | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV61385699; called by muse, mutect2
- CAPSL | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV68437172, COSV68438037, COSV68439298; called by muse, mutect2, varscan2
- CBLIF | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV57237951; called by muse, mutect2, varscan2
- CCDC7 | c.2473T>A p.S825T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.981); catalogued as rs1403604794, COSV56536655; called by muse, mutect2, varscan2
- CDH10 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177955408, COSV52570069, COSV52589927; called by muse, mutect2, varscan2
- CDH22 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1021321510, COSV64836468; called by muse, mutect2, varscan2
- CENPF | c.7996G>C p.E2666Q | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV65272678; called by muse, mutect2, varscan2
- CENPN | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV54728765; called by muse, mutect2, varscan2
- CFAP43 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.604); catalogued as COSV53376287; called by muse, mutect2, varscan2
- CHST7 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as COSV52099021; called by muse, mutect2, varscan2
- COL11A1 | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV62172949; called by muse, mutect2, varscan2
- CTAGE1 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775961866, COSV66942887; called by muse, mutect2, varscan2
- CYP39A1 | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV51493391, COSV51495437; called by muse, mutect2, varscan2
- CYP4F11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs771510465, COSV56125612; called by muse, mutect2
- DCT | c.864-2A>T p.X288_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as COSV65467444; called by muse, mutect2, varscan2
- DDX42 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.344); catalogued as COSV63789304, COSV63790576; called by muse, mutect2, varscan2
- DDX6 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV50587611; called by muse, mutect2, varscan2
- DMBT1 | c.2001T>A p.D667E | Missense Mutation (SNP) | VAF 111/206 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.552); catalogued as rs756134511, COSV57534523; called by muse, mutect2, varscan2
- DNAJC14 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs755633581, COSV54477742; called by muse, mutect2, varscan2
- DSCAM | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs770132126, COSV68020895; called by muse, mutect2, varscan2
- DYNC2H1 | c.6214G>T p.D2072Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62086178; called by muse, mutect2, varscan2
- EEF1A2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53204763; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV66964378; called by muse, mutect2, varscan2
- EFCAB1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV50617845; called by muse, mutect2, varscan2
- EFCAB5 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs767868545, COSV57926096; called by muse, mutect2, varscan2
- EGFLAM | c.2241G>C p.K747N | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as COSV59293360; called by muse, mutect2, varscan2
- EMID1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747987026, COSV61828451; called by muse, mutect2, varscan2
- EP400 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57762677; called by muse, mutect2, varscan2
- ETS1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60091806; called by muse, mutect2, varscan2
- EYS | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs767478184, COSV60976096; called by muse, mutect2, varscan2
- FAM135B | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV50522397, COSV50532956; called by muse, mutect2, varscan2
- FBF1 | c.328G>A p.E110K (on ENST00000586717; = p.E124K on NM_001319193.1) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.382); catalogued as rs1209850498, COSV59863596; called by muse, mutect2, varscan2
- FBXO43 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 102/144 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV71053296; called by muse, mutect2, varscan2
- FUBP1 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs762636934, COSV53926275; called by muse, mutect2, varscan2
- GABRG1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV54950026; called by muse, mutect2, varscan2
- GNL3L | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV60575232, COSV60575355; called by muse, mutect2, varscan2
- GPR22 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV51742811; called by muse, mutect2, varscan2
- GRIK1 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58710784; called by muse, mutect2, varscan2
- GRIN2A | c.3728G>T p.G1243V | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410743, COSV58020221; called by muse, mutect2, varscan2
- HERC2 | c.7003C>A p.H2335N | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV55307604, COSV99870347; called by muse, mutect2, varscan2
- HSP90AA1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53487391; called by muse, mutect2, varscan2
- HSPG2 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV65968979; called by muse, mutect2, varscan2
- IL23R | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV61372727; called by muse, varscan2
- ILF3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV51554151; called by muse, mutect2, varscan2
- INPP5D | c.1899C>T p.F633= (on ENST00000445964 / NM_001017915.3; = p.F632= on NM_005541.5) | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as rs375044485; called by muse, mutect2
- IP6K1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV58662808; called by muse, mutect2, varscan2
- JARID2 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV59185315; called by muse, mutect2, varscan2
- KARS1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as rs1000016910, COSV56690657; called by muse, mutect2, varscan2
- LGALS9 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780439566, COSV56347947; called by muse, mutect2, varscan2
- LHFPL6 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV65443689; called by muse, mutect2, varscan2
- LIMCH1 | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV100574236, COSV58273256; called by muse, mutect2, varscan2
- LSP1 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61132282; called by muse, mutect2, varscan2
- MACF1 | c.13153G>A p.E4385K (on ENST00000372915; = p.E2318K on NM_012090.5) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV57105793; called by muse, mutect2, varscan2
- MAD1L1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV56226416, COSV99767050; called by muse, mutect2, varscan2
- MAGEC2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 117/194 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV55997721; called by muse, mutect2, varscan2
- MAPK15 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV62027301; called by muse, mutect2, varscan2
- MAST1 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52241039; called by muse, mutect2
- MED12L | c.5513G>C p.R1838T | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV56368520, COSV56374022; called by muse, mutect2, varscan2
- MLLT10 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as rs943664282, COSV56991215; called by muse, mutect2, varscan2
- MOAP1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 130/284 reads (46%) | catalogued as COSV52092420; called by muse, mutect2, varscan2
- MOCOS | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV54340988; called by muse, mutect2, varscan2
- MPDZ | c.5236G>A p.D1746N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs767397676, COSV59915520; called by muse, mutect2
- MSX2 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV53326456; called by muse, mutect2, varscan2
- MUC16 | c.38186G>C p.R12729T | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV67444827; called by muse, mutect2, varscan2
- MUC16 | c.11263C>G p.Q3755E | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV67444833; called by muse, mutect2, varscan2
- MYH1 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 244/471 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752939333, COSV56843686, COSV99877217; called by muse, mutect2, varscan2
- MYO18A | c.1726C>G p.Q576E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV62862374; called by muse, mutect2, varscan2
- MYOZ1 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV63771502; called by muse, mutect2, varscan2
- NALCN | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV51917925; called by muse, mutect2, varscan2
- NANOS2 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs942500671, COSV58024721; called by muse, mutect2, varscan2
- NDE1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.037); catalogued as rs745889089, COSV61270057; called by muse, mutect2, varscan2
- NDUFS6 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs1274780971, COSV56875768; called by muse, mutect2, varscan2
- NELL2 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 29/173 reads (17%) | catalogued as COSV61568097; called by muse, mutect2, varscan2
- NKTR | c.2525G>C p.R842T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as COSV51769316; called by muse, mutect2, varscan2
- NLRP4 | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV56707850; called by muse, mutect2, varscan2
- OR13C8 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs756375125, COSV58610440, COSV58612121; called by muse, mutect2, varscan2
- P2RX5 | c.534G>A p.E178= | Splice Region (SNP) | VAF 52/252 reads (21%) | catalogued as COSV56590743; called by muse, mutect2, varscan2
- PCDH8 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.832); catalogued as COSV58810756; called by muse, mutect2
- PCDHAC2 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1554231530, COSV53836901, COSV99154926; called by muse, mutect2, varscan2
- PDZK1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 25/559 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376348039, COSV61092217; called by muse, mutect2
- PIK3CD | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV63126952; called by muse, mutect2, varscan2
- PLCL2 | c.914C>T p.T305M (on ENST00000615277 / NM_001144382.2; = p.T179M on NM_015184.5) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as rs369709033; called by muse, mutect2, varscan2
- PLS1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV61832718; called by muse, mutect2, varscan2
- POLD2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs568159170, COSV56255416; called by muse, mutect2, varscan2
- POLK | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV54031774; called by muse, mutect2, varscan2
- POLK | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54031815; called by muse, mutect2, varscan2
- PPIL4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.221); catalogued as rs1243852020; called by muse, mutect2, varscan2
- PRKDC | c.8577G>A p.Q2859= | Splice Region (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100037899, COSV58042760; called by muse, mutect2, varscan2
- PSG2 | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 46/553 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.248); catalogued as rs142667584; called by muse, mutect2
- RASEF | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 193/283 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV64585842; called by muse, mutect2, varscan2
- RBM22 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV52270321; called by muse, mutect2, varscan2
- RET | c.2996C>A p.A999E | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as COSV60686935, COSV60701201; called by muse, mutect2, varscan2
- RNASE4 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59011431; called by muse, mutect2, varscan2
- RNF17 | c.2527C>G p.L843V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1341724843, COSV55033942, COSV55035196; called by muse, mutect2
- RNF213 | c.2153C>A p.T718N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV60618978; called by muse, mutect2, varscan2
- RNGTT | c.1440-2A>G p.X480_splice | Splice Site (SNP) | VAF 24/56 reads (43%) | catalogued as COSV55646044, COSV55646575; called by muse, mutect2, varscan2
- RTP2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64078772; called by muse, mutect2, varscan2
- RUNX1 | c.614G>T p.R205L (on ENST00000344691 / NM_001001890.3; = p.R232L on NM_001754.5) | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55867388, COSV55883399; called by muse, mutect2, varscan2
- SAE1 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1320866693, COSV54293202; called by muse, mutect2, varscan2
- SCAF1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs770076860; called by muse, mutect2, varscan2
- SEMA3C | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54841263; called by muse, mutect2, varscan2
- SEMA6D | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs759832520, COSV60372830; called by muse, mutect2, varscan2
- SENP5 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60205974; called by muse, mutect2, varscan2
- SERPINC1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.893); catalogued as CD002477, COSV62928844, COSV62929140; called by muse, mutect2, varscan2
- SEZ6L2 | c.883C>T p.R295W (on ENST00000308713 / NM_001114099.3; = p.R225W on NM_012410.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs545967635, COSV58097157, COSV58099604; called by muse, mutect2, varscan2
- SF1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs1247342637, COSV57111413; called by muse, mutect2, varscan2
- SIPA1L2 | c.4022C>G p.S1341C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs759170556, COSV53383522; called by muse, mutect2, varscan2
- SIRT1 | c.1896G>C p.Q632H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV53017043; called by muse, mutect2, varscan2
- SLC12A5 | c.1953C>G p.I651M (on ENST00000454036 / NM_001134771.2; = p.I628M on NM_020708.5) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV54788360; called by muse, mutect2, varscan2
- SLC12A5 | c.2029C>G p.R677G (on ENST00000454036 / NM_001134771.2; = p.R654G on NM_020708.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54788385; called by muse, mutect2
- SLC22A25 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60594467; called by muse, mutect2, varscan2
- SLC35B3 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145512512; called by muse, mutect2, varscan2
- SMCHD1 | c.3094C>G p.P1032A | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55251610; called by muse, mutect2, varscan2
- SMCHD1 | c.3214C>G p.Q1072E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.708); catalogued as COSV55251631, COSV99861763; called by muse, mutect2, varscan2
- SMURF1 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63155696; called by muse, varscan2
- SMURF1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 76/397 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV63155705; called by muse, varscan2
- SPON1 | c.976T>A p.W326R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59957568; called by muse, mutect2, varscan2
- ST7 | c.1360C>G p.L454V (on ENST00000446490; = p.P531= on NM_018412.4) | Missense Mutation (SNP) | VAF 97/589 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60641071; called by muse, mutect2, varscan2
- ST8SIA6 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV66465822; called by muse, mutect2, varscan2
- STX4 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58267835; called by muse, mutect2, varscan2
- SUCLG1 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs539350409, COSV67264648; called by muse, mutect2, varscan2
- SUSD2 | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV54077573; called by muse, mutect2, varscan2
- SYNDIG1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV65232050; called by muse, mutect2, varscan2
- SYT15 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100970446; called by mutect2, varscan2
- TACC1 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 36/264 reads (14%) | catalogued as rs149014810; called by muse, mutect2, varscan2
- TAF2 | c.2739G>A p.M913I | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV65416523; called by muse, mutect2
- TAS2R20 | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV67852237; called by muse, mutect2, varscan2
- TCF25 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as COSV54524386; called by muse, mutect2, varscan2
- TMEM139 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60081385; called by muse, mutect2, varscan2
- TOMM70 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.069); catalogued as COSV52522222; called by muse, mutect2, varscan2
- TRAV19 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs762651432; called by muse, mutect2, varscan2
- TRIM8 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV56659512; called by muse, mutect2, varscan2
- TRMO | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64292917; called by muse, mutect2, varscan2
- TYW1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV55887052; called by muse, mutect2, varscan2
- UBE2B | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV54760060, COSV54760907; called by muse, mutect2, varscan2
- UPRT | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs199953225, COSV64912111; called by muse, mutect2, varscan2
- VARS2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as COSV58911226; called by muse, mutect2, varscan2
- VASH1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780884507, COSV51335214; called by muse, mutect2, varscan2
- WRN | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53296078; called by muse, mutect2
- XIRP2 | c.2303G>C p.G768A (on ENST00000628543; = p.G943A on NM_152381.6) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54682782, COSV54694609; called by muse, mutect2, varscan2
- XYLT1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as COSV54477321; called by muse, mutect2, varscan2
- ZBTB7A | c.1157T>A p.I386N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59326171; called by muse, mutect2, varscan2
- ZC3H11A | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 129/188 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs377447184; called by muse, mutect2, varscan2
- ZC3H18 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs762542605, COSV56322555; called by muse, varscan2
- ZFHX4 | c.5039C>G p.S1680C | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV50494202; called by muse, mutect2, varscan2
- ZFP36L2 | c.775A>G p.S259G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56697061; called by muse, mutect2, varscan2
- ZFR2 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs575924514, COSV53596371, COSV53602679; called by muse, mutect2, varscan2
- ZFYVE26 | c.2156G>A p.R719K | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV61324408; called by muse, mutect2, varscan2
- ZKSCAN1 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs759540374, COSV60872986; called by muse, mutect2, varscan2
- ZNF131 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV61001138; called by muse, varscan2
- ZNF236 | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV53482325; called by muse, mutect2, varscan2
- ZNF672 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs749923397; called by muse, mutect2, varscan2
- ZNF678 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV59380185, COSV59384259; called by muse, mutect2, varscan2
- ZNF831 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1011172094, COSV64037363; called by muse, mutect2, varscan2
- AEN | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- COL11A1 | c.2062G>C p.G688R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DNAH17 | c.11069T>A p.I3690N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- DUSP11 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 77/124 reads (62%) | called by muse, mutect2, varscan2
- IKZF4 | c.970A>T p.K324* | Nonsense Mutation (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2
- LAMA3 | c.2297C>G p.S766* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.7738C>T p.Q2580* | Nonsense Mutation (SNP) | VAF 99/142 reads (70%) | called by muse, mutect2, varscan2
- MMP9 | c.816del p.S273Afs*65 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel, varscan2
- MYO19 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NSMAF | c.1893-1G>C p.X631_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- PCNX3 | c.3277_3279del p.F1093del | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by pindel, varscan2
- SLC17A2 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- SMAD9 | c.914C>G p.S305* (on ENST00000379826 / NM_001127217.3; = p.S268* on NM_005905.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- SYNE1 | c.10084C>T p.Q3362* (on ENST00000367255 / NM_182961.4; = p.Q3369* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- TCAF1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2
- ACOT12 | c.843C>T p.I281= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs570010175, COSV100296793, COSV56892559; called by muse, mutect2, varscan2
- ADCY2 | c.453G>A p.L151= | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as COSV57859039; called by muse, mutect2
- ATXN2L | c.798G>A p.V266= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57365207; called by muse, mutect2
- BAZ1B | c.1032G>A p.K344= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs368184813; called by muse, mutect2, varscan2
- BCL11B | c.1737G>A p.A579= (on ENST00000357195 / NM_001282237.2; = p.A508= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs762694354, COSV61733237, COSV61734606; called by muse, mutect2, varscan2
- BCL9 | c.3231C>T p.L1077= | Silent (SNP) | VAF 112/350 reads (32%) | catalogued as COSV52340968; called by muse, mutect2, varscan2
- C12orf71 | c.129T>C p.D43= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs374528252; called by muse, mutect2, varscan2
- CAMSAP3 | c.3483C>G p.L1161= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV50330841, COSV99351515; called by muse, mutect2, varscan2
- CDH4 | c.2619C>T p.S873= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs549406943, COSV64642070, COSV64673335; called by muse, mutect2, varscan2
- CREB3 | c.465G>C p.R155= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV59204081; called by muse, mutect2, varscan2
- CTC1 | c.426G>C p.L142= | Silent (SNP) | VAF 42/291 reads (14%) | catalogued as COSV59852027; called by muse, mutect2, varscan2
- DMBT1 | c.7572C>T p.V2524= (on ENST00000338354 / NM_001377530.1; = p.V1767= on NM_004406.3) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV57534536; called by muse, mutect2, varscan2
- DNAAF3 | c.276G>A p.L92= (on ENST00000524407 / NM_001256715.2; = p.L139= on NM_178837.4) | Silent (SNP) | VAF 49/72 reads (68%) | catalogued as COSV66992175; called by muse, mutect2, varscan2
- EDNRA | c.126C>A p.G42= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV60095644; called by muse, mutect2, varscan2
- EXOC3 | c.1743C>T p.N581= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as rs760078189, COSV59265569; called by muse, mutect2
- FBXO42 | c.894C>T p.I298= | Silent (SNP) | VAF 45/61 reads (74%) | catalogued as COSV65044498; called by muse, mutect2, varscan2
- FLOT1 | c.972C>G p.A324= | Silent (SNP) | VAF 26/303 reads (9%) | catalogued as COSV64508021; called by muse, mutect2
- FLRT2 | c.1575A>G p.T525= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs1465351505, COSV58136269, COSV58141195; called by muse, mutect2, varscan2
- FOXE3 | c.480C>T p.F160= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV58632356; called by mutect2, varscan2
- GRIK2 | c.2304T>C p.T768= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV59712363; called by muse, mutect2, varscan2
- GRK2 | c.1359C>T p.F453= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV57950390; called by muse, mutect2, varscan2
- IGKV1-8 | c.246C>T p.F82= | Silent (SNP) | VAF 153/281 reads (54%) | called by muse, mutect2, varscan2
- IL23R | c.570G>A p.K190= | Silent (SNP) | VAF 83/129 reads (64%) | catalogued as COSV61372731; called by muse, varscan2
- INO80D | c.2634G>A p.V878= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs756025853, COSV68958095; called by muse, mutect2, varscan2
- KATNIP | c.3267G>A p.V1089= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV55173567; called by muse, mutect2, varscan2
- KCNC4 | c.1203C>T p.Y401= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as rs751851910, COSV63925007; called by muse, mutect2, varscan2
- KCNU1 | c.225G>A p.R75= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV67753088; called by muse, mutect2, varscan2
- KIAA1755 | c.384C>G p.L128= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as COSV54073645; called by muse, mutect2, varscan2
- LDLRAD3 | c.660G>A p.L220= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV59678399; called by muse, mutect2, varscan2
- LYST | c.2706C>G p.L902= | Silent (SNP) | VAF 70/259 reads (27%) | catalogued as rs1348336688, COSV67703301; called by muse, mutect2, varscan2
- MEGF8 | c.6501G>A p.P2167= (on ENST00000251268 / NM_001271938.2; = p.P2100= on NM_001410.3) | Silent (SNP) | VAF 71/105 reads (68%) | catalogued as rs145990797, COSV52085232; called by muse, mutect2, varscan2
- MEIS3 | c.918C>A p.I306= (on ENST00000558555 / NM_001346148.1; = p.I352= on NM_020160.3) | Silent (SNP) | VAF 66/99 reads (67%) | catalogued as COSV58982840; called by muse, mutect2, varscan2
- MYH13 | c.2250C>A p.L750= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs1204372036, COSV52820789; called by muse, mutect2, varscan2
- MYH3 | c.2853C>G p.L951= | Silent (SNP) | VAF 126/440 reads (29%) | catalogued as COSV56860903, COSV56868560; called by muse, mutect2, varscan2
- MYO3B | c.3135C>G p.L1045= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV58694396; called by muse, mutect2, varscan2
- OBSCN | c.99C>T p.I33= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs768211583, COSV52739926; called by muse, mutect2, varscan2
- OR5D13 | c.630G>A p.V210= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV62332697; called by muse, mutect2, varscan2
- PATJ | c.1389A>G p.P463= | Silent (SNP) | VAF 133/196 reads (68%) | catalogued as COSV57155474; called by muse, mutect2, varscan2
- PCDHAC2 | c.2169C>T p.I723= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV53836896; called by muse, mutect2, varscan2
- PCNT | c.3729C>T p.L1243= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs1569239470, COSV64025043; called by muse, mutect2, varscan2
- PEG3 | c.2643T>C p.P881= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV55624705; called by muse, mutect2, varscan2
- PLEKHA5 | c.249C>T p.T83= | Silent (SNP) | VAF 114/199 reads (57%) | catalogued as COSV54694077; called by muse, mutect2, varscan2
- POC5 | c.1623G>T p.R541= (on ENST00000428202 / NM_001099271.2; = p.R516= on NM_152408.2) | Silent (SNP) | VAF 99/184 reads (54%) | catalogued as COSV66841512, COSV66843310; called by muse, mutect2, varscan2
- PPP1R12B | c.2943C>G p.S981= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV51781683; called by muse, mutect2, varscan2
- PRKG2 | c.27A>G p.K9= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2
- PRRC2A | c.4539G>A p.R1513= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV65685074; called by muse, mutect2, varscan2
- RACGAP1 | c.1032C>G p.V344= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV56698508; called by muse, mutect2, varscan2
- RBCK1 | c.162C>T p.D54= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV62291653; called by muse, mutect2, varscan2
- RBM42 | c.1290G>A p.K430= | Silent (SNP) | VAF 104/234 reads (44%) | catalogued as COSV52896736; called by muse, mutect2, varscan2
- RYR2 | c.6471G>A p.Q2157= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV63662007; called by muse, mutect2, varscan2
- SLC5A7 | c.1266T>C p.L422= | Silent (SNP) | VAF 54/100 reads (54%) | catalogued as COSV50888924; called by muse, mutect2, varscan2
- STIL | c.438C>T p.F146= | Silent (SNP) | VAF 50/81 reads (62%) | catalogued as COSV54547646; called by muse, mutect2, varscan2
- SYNGR2 | c.291C>T p.N97= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs370592724; called by muse, mutect2, varscan2
- TMC8 | c.1467C>G p.L489= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV59208613; called by muse, mutect2, varscan2
- TMEM63A | c.429G>A p.Q143= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as COSV64762352; called by muse, mutect2, varscan2
- TMLHE | c.873C>T p.L291= | Silent (SNP) | VAF 91/140 reads (65%) | catalogued as COSV57686257, COSV57686796; called by muse, mutect2, varscan2
- TYK2 | c.138C>T p.F46= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV53384750; called by muse, mutect2, varscan2
- UBE3B | c.1140G>A p.L380= | Silent (SNP) | VAF 120/201 reads (60%) | catalogued as COSV55091190; called by muse, mutect2, varscan2
- VPS53 | c.543G>A p.V181= (on ENST00000571805 / NM_001366253.2; = p.V152= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/305 reads (8%) | catalogued as COSV52126158; called by muse, mutect2
- WNK4 | c.1551C>A p.I517= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV55901480; called by muse, mutect2, varscan2
- ZBTB7A | c.1275G>A p.L425= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100475698; called by muse, mutect2
- ZNF232 | c.1029C>T p.S343= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as COSV51502432; called by muse, mutect2
- ZNF569 | c.153C>T p.F51= | Silent (SNP) | VAF 62/878 reads (7%) | catalogued as COSV57593574; called by muse, mutect2
- ZNF587 | c.1482C>T p.C494= | Silent (SNP) | VAF 44/281 reads (16%) | catalogued as rs755428091, COSV57146714; called by muse, mutect2, varscan2
- ARPP21 | c.2032+575del | Intron (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- GLRX5 | chr14:95533588 C>G | 5'Flank (SNP) | VAF 99/224 reads (44%) | catalogued as rs376387449; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.727G>C | RNA (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- RBCK1 | c.167+431C>G | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as COSV62293280; called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520604 C>T | 3'Flank (SNP) | VAF 93/574 reads (16%) | catalogued as COSV55419818; called by muse, mutect2, varscan2
